Somatic mutation profile of tumor specimen TCGA-A6-5665-01A (aliquot TCGA-A6-5665-01A-01D-1650-10) from TCGA case TCGA-A6-5665, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 84.6 years (30,915 days).
Specimen TCGA-A6-5665-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ed24154-ad44-4203-946b-f0bec378c36e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-5665-10A (Blood Derived Normal), aliquot TCGA-A6-5665-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e64c3ce9-74a2-4804-8179-e57459b09e59

The open-access MAF lists 2,133 somatic variants for this specimen: 1,648 protein-altering or splice-affecting, 440 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,086, Silent 440, Frame Shift Del 272, Frame Shift Ins 153, Nonsense Mutation 69, Splice Site 28, Intron 21, Splice Region 19, In Frame Del 11, 3'UTR 10, RNA 6, In Frame Ins 4.

Variants (750 of 2,133; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANO5 | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 156/428 reads (36%) | catalogued as rs1168346560, CM117893, COSV61083716; ClinVar: pathogenic; called by muse, varscan2
- APOA1 | c.85del p.Q29Rfs*7 | Frame Shift Del (DEL) | VAF 23/76 reads (30%) | catalogued as rs753348565, CD961783; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ATM | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 114/319 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs202160435, COSV53723910, COSV53729033; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1155dup p.I386Hfs*56 | Frame Shift Ins (INS) | VAF 29/98 reads (30%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, varscan2
- AXIN2 | c.1994dup p.N666Qfs*41 | Frame Shift Ins (INS) | VAF 17/46 reads (37%) | catalogued as rs267606674; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AXL | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 33/104 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs374699228; called by muse, mutect2, varscan2
- BCL10 | c.499del p.S167Lfs*6 | Frame Shift Del (DEL) | VAF 59/177 reads (33%) | catalogued as rs387906350, COSV65354275; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRCA2 | c.7543dup p.T2515Nfs*24 | Frame Shift Ins (INS) | VAF 52/177 reads (29%) | catalogued as rs80359657; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CACNA1A | c.3544dup p.L1182Pfs*38 | Frame Shift Ins (INS) | VAF 24/90 reads (27%) | catalogued as rs757953057; ClinVar: pathogenic; called by mutect2, varscan2
- CDK12 | c.2669G>A p.R890H | Missense Mutation (SNP) | VAF 78/190 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV71000029; called by muse, mutect2, varscan2
- CENPF | c.5920dup p.T1974Nfs*9 | Frame Shift Ins (INS) | VAF 44/164 reads (27%) | catalogued as rs757531591; ClinVar: pathogenic; called by mutect2, varscan2
- COL2A1 | c.2710C>T p.R904C | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs121912882, CM980396, COSV61528961; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COLEC11 | c.610G>A p.G204S | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387907076, CM111429, COSV52592797; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FLCN | c.1285dup p.H429Pfs*27 | Frame Shift Ins (INS) | VAF 20/66 reads (30%) | catalogued as rs80338682; ClinVar: pathogenic; called by mutect2, varscan2
- GATA2 | c.599del p.G200Vfs*18 | Frame Shift Del (DEL) | VAF 37/128 reads (29%) | catalogued as rs768767517, CD141459, COSV62006544, COSV62006643; ClinVar: pathogenic; called by mutect2, varscan2
- GNAQ | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 53/178 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as rs397514698, CM1412391, COSV54106047, COSV54107425; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TPO | c.2421del p.C808Afs*24 | Frame Shift Del (DEL) | VAF 14/47 reads (30%) | catalogued as rs760307139, COSV100220194; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TSHR | c.1342G>A p.V448I | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201889708, COSV53317507; ClinVar: benign / uncertain significance / likely pathogenic; called by muse, varscan2
- AAAS | c.839T>C p.V280A | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.108); catalogued as COSV99266848; called by muse, mutect2, varscan2
- ABCA7 | c.4634C>T p.A1545V | Missense Mutation (SNP) | VAF 82/204 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54027176; called by muse, mutect2, varscan2
- ABCB1 | c.2296T>A p.S766T | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.798); catalogued as COSV55948438; called by muse, mutect2, varscan2
- ABCD2 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 86/216 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.019); catalogued as COSV58051020; called by muse, mutect2, varscan2
- ABCE1 | c.1524A>G p.I508M | Missense Mutation (SNP) | VAF 126/326 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.903); catalogued as COSV99668437; called by muse, mutect2, varscan2
- ABHD18 | c.1064T>C p.V355A (on ENST00000398965 / NM_001039717.2; = p.V262A on NM_025097.2 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/212 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV66293522; called by muse, mutect2, varscan2
- ACACB | c.5993A>C p.D1998A | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58131553; called by muse, mutect2, varscan2
- ACAN | c.6917del p.P2306Lfs*10 | Frame Shift Del (DEL) | VAF 27/78 reads (35%) | catalogued as rs777726601; called by mutect2, pindel, varscan2
- ACKR4 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 240/1031 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1398393923, COSV51442163; called by muse, mutect2, varscan2
- ACOT9 | c.373+2T>C p.X125_splice | Splice Site (SNP) | VAF 125/357 reads (35%) | catalogued as rs746954701, COSV100321216; called by muse, mutect2, varscan2
- ACTA1 | c.911del p.G304Afs*24 | Frame Shift Del (DEL) | VAF 54/180 reads (30%) | catalogued as CD142756, COSV64203291; called by mutect2, pindel, varscan2
- ACTB | c.302A>G p.H101R | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.976); catalogued as rs1341717668, COSV59317914; called by muse, mutect2, varscan2
- ACTL6B | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV50514252; called by muse, mutect2, varscan2
- ACVR2A | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 105/284 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV54020809; called by muse, mutect2, varscan2
- ADA2 | c.1403A>G p.D468G (on ENST00000262607; = p.D227G on NM_177405.3) | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV52830988; called by muse, mutect2, varscan2
- ADAD1 | c.244dup p.I82Nfs*3 | Frame Shift Ins (INS) | VAF 104/334 reads (31%) | catalogued as rs746068816; called by mutect2, varscan2
- ADAD2 | c.1514G>A p.R505H (on ENST00000315906 / NM_001145400.2; = p.R587H on NM_139174.4) | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.061); catalogued as rs1298845639, COSV51893045; called by muse, mutect2, varscan2
- ADAMTS20 | c.2355del p.E786Kfs*86 | Frame Shift Del (DEL) | VAF 25/92 reads (27%) | catalogued as rs1177283960; called by mutect2, pindel, varscan2
- ADAMTS4 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs1243925734, COSV63487580; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1826C>T p.P609L | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as COSV54998441; called by muse, mutect2, varscan2
- ADAP1 | c.577del p.H193Tfs*8 | Frame Shift Del (DEL) | VAF 43/154 reads (28%) | catalogued as rs1284945590; called by mutect2, pindel, varscan2
- ADCK2 | c.31G>A p.V11I | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.124); catalogued as COSV50781009; called by muse, mutect2, varscan2
- ADD3 | c.1207G>T p.D403Y | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53321538; called by muse, mutect2, varscan2
- ADGRG2 | c.2776A>C p.S926R (on ENST00000379869 / NM_001079858.3; = p.S923R on NM_005756.4) | Missense Mutation (SNP) | VAF 117/388 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61338393; called by muse, mutect2
- ADGRG3 | c.1070G>A p.G357D | Missense Mutation (SNP) | VAF 61/165 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV59650667; called by muse, mutect2, varscan2
- ADGRV1 | c.13307T>C p.F4436S | Missense Mutation (SNP) | VAF 97/288 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV67982633; called by muse, mutect2, varscan2
- AFAP1 | c.2081C>A p.P694Q | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61794747; called by muse, mutect2, varscan2
- AGRN | c.1345C>T p.Q449* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as rs1255938863, COSV65068794; called by muse, mutect2, varscan2
- AGRN | c.5693G>A p.R1898H | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs142132521; called by muse, mutect2, varscan2
- AHNAK | c.16265T>C p.V5422A | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV99946057; called by muse, varscan2
- AHNAK2 | c.16178G>T p.R5393M | Missense Mutation (SNP) | VAF 65/208 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.716); catalogued as COSV60912091; called by muse, mutect2, varscan2
- AJAP1 | c.902T>C p.L301P | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65450184; called by muse, varscan2
- AJM1 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs375917223, COSV99915504; called by muse, mutect2, varscan2
- AJM1 | c.1637C>T p.P546L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.247); catalogued as rs770142218, COSV56031902; called by muse, mutect2, varscan2
- AK1 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.317); catalogued as rs375921903, COSV56345177; called by muse, mutect2, varscan2
- AK9 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 143/451 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs150756404; called by muse, mutect2, varscan2
- AKAP7 | c.236dup p.R80Efs*24 | Frame Shift Ins (INS) | VAF 128/452 reads (28%) | catalogued as rs763109484; called by mutect2, varscan2
- AKAP9 | c.1874T>C p.L625P | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62342836; called by muse, mutect2
- AKAP9 | c.3128G>C p.G1043A | Missense Mutation (SNP) | VAF 71/213 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.311); catalogued as COSV62342849; called by muse, mutect2, varscan2
- AKNAD1 | c.1711G>T p.D571Y | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV62197029; called by muse, varscan2
- AKT1S1 | c.495del p.T166Pfs*87 (on ENST00000344175 / NM_001098633.4; = p.T186Pfs*87 on NM_032375.5) | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as rs748776119, COSV59276444; called by mutect2, varscan2
- ALB | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 110/330 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs267600248, COSV55736977, COSV55739910; called by muse, mutect2, varscan2
- ALDH16A1 | c.1382C>T p.S461L | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs768690823, COSV53193518; called by muse, mutect2, varscan2
- ALDH16A1 | c.1642C>T p.R548W | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs780408604, COSV53193532; called by muse, varscan2
- ALG5 | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99523539; called by muse, mutect2, varscan2
- ALKBH4 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.18); catalogued as COSV52960719; called by muse, mutect2, varscan2
- ANGPTL7 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs753003549, COSV100815803; called by muse, mutect2, varscan2
- ANK3 | c.12420del p.K4140Nfs*15 (on ENST00000280772 / NM_001320874.2; = p.K661Nfs*15 on NM_001149.3) | Frame Shift Del (DEL) | VAF 64/208 reads (31%) | catalogued as rs1466658148; called by mutect2, pindel, varscan2
- ANKLE2 | c.1319A>G p.N440S | Missense Mutation (SNP) | VAF 100/334 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.09); catalogued as COSV61708644; called by muse, mutect2, varscan2
- ANKS1A | c.2323G>A p.V775M | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as rs762067571, COSV64459812; called by muse, mutect2, varscan2
- ANKS1A | c.2465G>A p.R822H | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780166520, COSV64459819; called by muse, mutect2, varscan2
- ANKS1B | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 91/255 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1359127931, COSV61335488; called by muse, mutect2, varscan2
- ANO8 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.959); catalogued as COSV99344161; called by muse, mutect2, varscan2
- ANXA2 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.101); catalogued as rs374077954; called by muse, mutect2, varscan2
- AOX1 | c.1561A>G p.S521G | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as COSV65980890; called by muse, mutect2
- AP1M1 | c.163del p.V55Sfs*182 | Frame Shift Del (DEL) | VAF 14/61 reads (23%) | catalogued as rs753324780, COSV52227333; called by mutect2, pindel
- AP3D1 | c.3169G>A p.A1057T | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.387); catalogued as rs764711501, COSV61424734; called by mutect2, varscan2
- AP3D1 | c.2873G>A p.S958N | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV61426334; called by muse, mutect2, varscan2
- AP3D1 | c.734T>C p.F245S | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61426342; called by muse, mutect2, varscan2
- AP3D1 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.688); catalogued as rs765088250, COSV61426354; called by muse, mutect2, varscan2
- AP3M2 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 112/361 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs151272027; called by muse, varscan2
- AP4B1 | c.958del p.C320Afs*21 | Frame Shift Del (DEL) | VAF 56/195 reads (29%) | catalogued as rs775095423; called by mutect2, pindel, varscan2
- APOB | c.12673G>A p.G4225R | Missense Mutation (SNP) | VAF 57/175 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV51930673; called by muse, mutect2, varscan2
- APOB | c.9016G>T p.G3006C | Missense Mutation (SNP) | VAF 63/191 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1456410181, COSV51930683; called by muse, mutect2, varscan2
- ARAP1 | c.1869del p.S624Vfs*107 (on ENST00000393609 / NM_001040118.2; = p.S379Vfs*107 on NM_015242.4) | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | catalogued as rs751080362, COSV100501527; called by mutect2, varscan2
- ARAP3 | c.2024T>C p.V675A | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.275); catalogued as rs749227449, COSV99499406; called by muse, mutect2
- ARFGEF2 | c.848A>G p.D283G | Missense Mutation (SNP) | VAF 84/247 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV64211568; called by muse, mutect2, varscan2
- ARFGEF2 | c.1834C>T p.R612W | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.586); catalogued as rs370911063; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARFGEF3 | c.1667C>T p.A556V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs1175780758, COSV52454502; called by muse, mutect2, varscan2
- ARHGAP33 | c.387dup p.E130Rfs*27 | Frame Shift Ins (INS) | VAF 16/62 reads (26%) | catalogued as rs772293323; called by mutect2, pindel, varscan2
- ARHGAP33 | c.1522G>A p.V508I | Missense Mutation (SNP) | VAF 67/192 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.211); catalogued as rs535794132, COSV50121111; called by muse, mutect2, varscan2
- ARHGAP6 | c.2635C>T p.R879W (on ENST00000337414 / NM_013427.3; = p.R676W on NM_013423.3) | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.965); catalogued as COSV57293977; called by muse, mutect2, varscan2
- ARHGDIB | c.515A>G p.Y172C | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56762873; called by muse, mutect2, varscan2
- ARHGEF1 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); catalogued as rs782343511, COSV61527129; called by muse, mutect2, varscan2
- ARHGEF11 | c.1670del p.P557Lfs*9 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | catalogued as COSV63816428; called by mutect2, pindel, varscan2
- ARHGEF18 | c.1300C>T p.R434C (on ENST00000359920 / NM_001130955.2; = p.R330C on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs756499530, COSV60468522, COSV60474868; called by muse, mutect2, varscan2
- ARHGEF18 | c.2086A>G p.R696G (on ENST00000359920 / NM_001130955.2; = p.R592G on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV100149142; called by muse, mutect2, varscan2
- ARHGEF26 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs994217053, COSV62845270; called by muse, varscan2
- ARHGEF28 | c.1219T>C p.C407R | Missense Mutation (SNP) | VAF 73/192 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs767417665, COSV55252489; called by muse, mutect2, varscan2
- ARHGEF28 | c.2968C>T p.R990* | Nonsense Mutation (SNP) | VAF 15/80 reads (19%) | catalogued as rs771514690, COSV55252501; called by muse, mutect2, varscan2
- ARHGEF40 | c.527T>C p.L176P | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV53879301; called by muse, mutect2
- ARID2 | c.3365T>C p.V1122A | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.097); catalogued as rs1476958272, COSV100535583; called by muse, mutect2, varscan2
- ARL6IP6 | c.400+2T>C p.X134_splice | Splice Site (SNP) | VAF 14/39 reads (36%) | catalogued as COSV58442484; called by muse, mutect2, varscan2
- ARNTL2 | c.1721C>T p.A574V | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.231); catalogued as rs11049005; called by muse, mutect2, varscan2
- ARRDC2 | c.316T>C p.F106L | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV55843990; called by muse, mutect2, varscan2
- ARSL | c.898G>A p.V300I | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); catalogued as rs752354785, COSV66965067; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARVCF | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as rs761726212, COSV99599002; called by muse, mutect2, varscan2
- ASB11 | c.95dup p.L32Ffs*14 | Frame Shift Ins (INS) | VAF 117/384 reads (30%) | catalogued as rs777775669; called by mutect2, varscan2
- ASH1L | c.6809A>G p.Q2270R (on ENST00000368346 / NM_001366177.2; = p.Q2265R on NM_018489.3) | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.928); catalogued as COSV64206851; called by muse, mutect2
- ASPN | c.241T>C p.C81R | Missense Mutation (SNP) | VAF 66/166 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65016025; called by muse, varscan2
- ASTN2 | c.2572C>T p.R858W (on ENST00000313400 / NM_001365069.1; = p.R807W on NM_014010.5) | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754101258, COSV57766765; called by muse, mutect2, varscan2
- ASTN2 | c.1675G>T p.G559* (on ENST00000313400 / NM_001365069.1; = p.G508* on NM_014010.5) | Nonsense Mutation (SNP) | VAF 52/141 reads (37%) | catalogued as COSV100525292, COSV57775594; called by muse, mutect2, varscan2
- ASTN2 | c.1579G>A p.D527N (on ENST00000313400 / NM_001365069.1; = p.D476N on NM_014010.5) | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as rs976057171, COSV57747261; called by muse, mutect2, varscan2
- ASXL1 | c.2535dup p.S846Qfs*5 | Frame Shift Ins (INS) | VAF 61/201 reads (30%) | catalogued as rs750170870; called by mutect2, pindel, varscan2
- ATG14 | c.1190T>C p.V397A | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV55956052; called by muse, mutect2, varscan2
- ATG7 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs772454167, COSV61611198; called by muse, mutect2, varscan2
- ATM | c.6031A>G p.S2011G | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV53736048; called by muse, varscan2
- ATP10A | c.2411C>T p.A804V | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs763990614, COSV63515700; called by muse, mutect2, varscan2
- ATP13A1 | c.1454T>C p.L485P | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52284362; called by muse, mutect2, varscan2
- ATP2B3 | c.3317G>A p.R1106Q | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as rs1557017728, COSV54843785; called by muse, mutect2, varscan2
- ATP2B3 | c.3524del p.P1175Rfs*12 | Frame Shift Del (DEL) | VAF 26/63 reads (41%) | catalogued as rs782513834; called by mutect2, varscan2
- ATP2C2 | c.1913C>T p.A638V | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV52294282; called by muse, mutect2, varscan2
- ATP4A | c.2665T>C p.W889R | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99382239; called by muse, mutect2
- ATP8A2 | c.1712+2T>C p.X571_splice | Splice Site (SNP) | VAF 84/281 reads (30%) | catalogued as COSV54945585; called by muse, mutect2, varscan2
- ATP8B1 | c.2609C>A p.P870H | Missense Mutation (SNP) | VAF 78/186 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52174207; called by muse, mutect2, varscan2
- ATP8B2 | c.536C>T p.A179V (on ENST00000672630; = p.A146V on NM_001005855.2) | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.244); catalogued as rs776939812, COSV59245184; called by muse, mutect2, varscan2
- AUTS2 | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 51/201 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV61392101, COSV61392824; called by muse, mutect2, varscan2
- AXL | c.1517G>A p.R506H (on ENST00000301178 / NM_021913.5; = p.R497H on NM_001699.6) | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1162584880, COSV56566309; called by muse, mutect2, varscan2
- B4GALNT2 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV55925515; called by muse, mutect2, varscan2
- BABAM2 | c.788A>G p.Y263C | Missense Mutation (SNP) | VAF 113/313 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV59620146; called by muse, mutect2, varscan2
- BAG6 | c.1169dup p.T391Nfs*29 | Frame Shift Ins (INS) | VAF 8/20 reads (40%) | catalogued as rs745882580; called by mutect2, varscan2
- BCAR1 | c.890T>G p.L297R | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as COSV99366137; called by muse, mutect2
- BCAR1 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1281183894, COSV50780130; called by muse, mutect2, varscan2
- BCOR | c.1404C>A p.H468Q | Missense Mutation (SNP) | VAF 72/190 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV100653002; called by muse, mutect2, varscan2
- BEND3 | c.2206G>A p.V736M | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1554231295, COSV64682447; called by muse, mutect2, varscan2
- BEST2 | c.152+2T>G p.X51_splice | Splice Site (SNP) | VAF 36/105 reads (34%) | catalogued as COSV99244272; called by muse, mutect2, varscan2
- BLM | c.563A>G p.K188R | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs907949967, COSV100757025; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMP6 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.072); catalogued as rs577694907, COSV51663347; called by muse, mutect2, varscan2
- BMPER | c.927+2T>C p.X309_splice | Splice Site (SNP) | VAF 35/104 reads (34%) | catalogued as COSV51814978; called by muse, mutect2, varscan2
- BMPR2 | c.464T>A p.L155* | Nonsense Mutation (SNP) | VAF 194/568 reads (34%) | catalogued as COSV65808473; called by muse, mutect2, varscan2
- BMPR2 | c.690del p.V231Cfs*21 | Frame Shift Del (DEL) | VAF 94/290 reads (32%) | catalogued as COSV65810054; called by mutect2, pindel, varscan2
- BMPR2 | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 65/214 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.7); catalogued as rs201440272, COSV65808479; called by muse, mutect2, varscan2
- BNIP3 | c.222G>T p.M74I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.042); catalogued as COSV100893173; called by muse, varscan2
- BNIP5 | c.1702del p.Y568Tfs*12 | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | catalogued as COSV71325486; called by mutect2, pindel, varscan2
- BOD1L1 | c.8392G>A p.A2798T | Missense Mutation (SNP) | VAF 64/239 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs774507896, COSV50009015; called by muse, mutect2, varscan2
- BRIP1 | c.1027C>A p.L343M | Missense Mutation (SNP) | VAF 83/231 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV51997190; called by muse, mutect2, varscan2
- BRSK2 | c.71C>T p.T24M | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV57542104; called by muse, mutect2
- BRSK2 | c.1052A>T p.D351V | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV57542109; called by muse, mutect2, varscan2
- BRWD1 | c.6809G>A p.R2270Q | Missense Mutation (SNP) | VAF 254/421 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.766); catalogued as rs1387048628, COSV59000046; called by muse, mutect2, varscan2
- BSN | c.10609A>G p.M3537V | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs778906963, COSV99607553; called by muse, mutect2
- BTBD17 | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1329577813; called by muse, varscan2
- BTNL9 | c.167A>G p.E56G | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs1396382490, COSV59794955; called by muse, mutect2, varscan2
- C10orf120 | c.898G>T p.D300Y | Missense Mutation (SNP) | VAF 63/197 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV61491793, COSV61492605; called by muse, mutect2, varscan2
- C10orf90 | c.395del p.G132Afs*76 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | catalogued as rs756932045; called by mutect2, pindel, varscan2
- C17orf75 | c.469G>T p.G157W | Missense Mutation (SNP) | VAF 66/207 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56752576; called by muse, mutect2, varscan2
- C1QL3 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.09); catalogued as COSV54348460; called by muse, mutect2, varscan2
- C1QTNF3 | c.475G>A p.V159I | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.549); catalogued as COSV51468193; called by muse, mutect2, varscan2
- C1orf159 | c.602A>G p.Q201R (on ENST00000379339 / NM_001330306.2; = p.Q165R on NM_017891.5) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV99618241; called by muse, mutect2, varscan2
- C2orf16 | c.4820G>A p.R1607H | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1047397156, COSV62674761; called by muse, mutect2, varscan2
- C4orf46 | c.292T>C p.W98R | Missense Mutation (SNP) | VAF 240/618 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs765140061, COSV57014581; called by muse, mutect2
- C6 | c.345G>T p.Q115H | Missense Mutation (SNP) | VAF 15/300 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99666659; called by muse, mutect2
- C7orf50 | c.215del p.K72Rfs*87 | Frame Shift Del (DEL) | VAF 38/124 reads (31%) | catalogued as COSV62475944; called by pindel, varscan2
- C7orf61 | c.620A>G p.*207Wext*10 | Nonstop Mutation (SNP) | VAF 25/74 reads (34%) | catalogued as COSV60092617; called by muse, mutect2, varscan2
- CABLES1 | c.847C>T p.R283W (on ENST00000256925 / NM_001100619.2; = p.R18W on NM_138375.2) | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs529420681, COSV56932228; called by muse, mutect2, varscan2
- CABLES1 | c.1568T>C p.M523T (on ENST00000256925 / NM_001100619.2; = p.M258T on NM_138375.2) | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV56932238; called by muse, mutect2
- CACNA1I | c.2524T>C p.F842L | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV100361999, COSV60809896; called by muse, mutect2, varscan2
- CACNA1I | c.5993G>A p.R1998Q | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs762336883, COSV60804825; called by muse, mutect2, varscan2
- CACNB1 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV59998500; called by muse, mutect2, varscan2
- CACUL1 | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 98/252 reads (39%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.014); catalogued as COSV60993654, COSV60994352; called by muse, mutect2, varscan2
- CADM1 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 102/290 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs768807528, COSV59002182; called by muse, mutect2, varscan2
- CAMK2G | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 139/363 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV59481051; called by muse, mutect2, varscan2
- CAND1 | c.46A>G p.T16A | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.415); catalogued as COSV73338853; called by muse, mutect2, varscan2
- CAPN2 | c.729+1G>A p.X243_splice | Splice Site (SNP) | VAF 37/102 reads (36%) | catalogued as rs549405629, COSV54335443; called by muse, mutect2, varscan2
- CAPS2 | c.1373A>G p.D458G | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV60824759; called by muse, mutect2, varscan2
- CARD10 | c.1578del p.S527Vfs*31 | Frame Shift Del (DEL) | VAF 12/53 reads (23%) | catalogued as rs35832225; called by mutect2, pindel, varscan2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 14/25 reads (56%) | catalogued as rs762770988, COSV62756627; called by mutect2, pindel, varscan2
- CARNS1 | c.2423A>G p.Q808R | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.715); catalogued as COSV100321808; called by muse, mutect2
- CASP8AP2 | c.821A>G p.E274G | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV52746193; called by muse, mutect2, varscan2
- CASZ1 | c.4022G>C p.G1341A | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.553); catalogued as rs376223327, COSV59734162; called by muse, mutect2, varscan2
- CBX8 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53936060; called by muse, mutect2, varscan2
- CBY2 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.555); catalogued as rs1371744667, COSV100137492; called by muse, mutect2, varscan2
- CCDC190 | c.36G>T p.K12N | Missense Mutation (SNP) | VAF 122/350 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV63362709; called by muse, varscan2
- CCDC190 | c.27A>C p.Q9H | Missense Mutation (SNP) | VAF 126/328 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV63362716; called by muse, varscan2
- CCDC39 | c.1388G>A p.R463Q | Missense Mutation (SNP) | VAF 72/237 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as rs747905187, COSV56481689; called by muse, varscan2
- CCDC88B | c.1915del p.W639Gfs*3 | Frame Shift Del (DEL) | VAF 28/65 reads (43%) | catalogued as COSV57265608; called by mutect2, varscan2
- CCDC88B | c.2936G>A p.R979Q | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs566542432, COSV57265614; called by muse, mutect2, varscan2
- CCDC93 | c.335A>T p.D112V | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60120630; called by muse, mutect2, varscan2
- CCDC9B | c.294del p.M99Wfs*3 | Frame Shift Del (DEL) | VAF 19/59 reads (32%) | catalogued as rs765438623; called by mutect2, pindel, varscan2
- CCNF | c.1391A>G p.H464R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.933); catalogued as COSV53539117; called by muse, mutect2
- CCNK | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 65/166 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs749729510, COSV66274837; called by muse, varscan2
- CCSAP | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 93/273 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1414465475, COSV52909113; called by muse, mutect2, varscan2
- CD200R1L | c.55A>G p.S19G | Missense Mutation (SNP) | VAF 73/237 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV68004039; called by muse, mutect2, varscan2
- CD27 | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.938); catalogued as rs763617266, COSV56949851; called by muse, mutect2, varscan2
- CD38 | c.138G>A p.W46* | Nonsense Mutation (SNP) | VAF 26/76 reads (34%) | catalogued as COSV56889242; called by muse, mutect2, varscan2
- CD52 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.666); catalogued as rs141117966; called by muse, mutect2, varscan2
- CD58 | c.308A>G p.Y103C | Missense Mutation (SNP) | VAF 135/391 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65664727; called by muse, mutect2, varscan2
- CDC23 | c.302G>T p.R101L | Missense Mutation (SNP) | VAF 80/221 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV67508357, COSV67508376; called by muse, mutect2, varscan2
- CDC73 | c.309A>G p.S103= | Splice Region (SNP) | VAF 38/296 reads (13%) | catalogued as COSV100813732; called by muse, mutect2
- CDH22 | c.1735del p.I579Sfs*4 | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | catalogued as COSV64837066; called by mutect2, pindel, varscan2
- CDH23 | c.7632G>T p.L2544F | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as rs775191895, COSV56456099; called by muse, mutect2, varscan2
- CDHR1 | c.89A>G p.N30S | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs757172364, COSV60561247; called by muse, mutect2, varscan2
- CDHR3 | c.1433C>T p.T478I | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as rs1407144190, COSV58415571; called by muse, mutect2, varscan2
- CDK1 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.876); catalogued as rs45540532, COSV100358778; called by muse, mutect2, varscan2
- CDK14 | c.805del p.E269Sfs*2 (on ENST00000380050 / NM_001287135.2; = p.E251Sfs*2 on NM_012395.3) | Frame Shift Del (DEL) | VAF 64/253 reads (25%) | catalogued as COSV56052544; called by mutect2, pindel, varscan2
- CDK5RAP2 | c.998del p.K333Rfs*76 | Frame Shift Del (DEL) | VAF 95/299 reads (32%) | catalogued as rs973156155; called by mutect2, pindel, varscan2
- CEACAM16 | c.865G>A p.G289R | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760693860, COSV69186495; called by muse, mutect2, varscan2
- CELSR3 | c.6965C>A p.P2322H | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV50845960; called by muse, mutect2, varscan2
- CENPE | c.3703G>T p.E1235* | Nonsense Mutation (SNP) | VAF 196/570 reads (34%) | catalogued as COSV54379091; called by muse, mutect2, varscan2
- CEP126 | c.352T>A p.F118I | Missense Mutation (SNP) | VAF 112/301 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54823687; called by muse, mutect2, varscan2
- CEP164 | c.1482del p.Q496Rfs*97 | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | catalogued as rs755923652, COSV54039972; called by mutect2, pindel, varscan2
- CEP250 | c.670A>G p.T224A | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs1407275854, COSV100698780; called by muse, mutect2, varscan2
- CEP250 | c.2698G>A p.A900T | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.781); catalogued as COSV100699200, COSV61169197; called by muse, varscan2
- CEP250 | c.2726G>A p.R909Q | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.086); catalogued as rs775429730, COSV61169204; called by muse, varscan2
- CEP290 | c.5327T>C p.V1776A | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100468019; called by muse, varscan2
- CEP68 | c.2135A>C p.K712T | Missense Mutation (SNP) | VAF 158/493 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV53124224; called by muse, mutect2, varscan2
- CES3 | c.1568C>T p.A523V | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs71649615; called by muse, mutect2, varscan2
- CES5A | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs761721054, COSV51865340; called by muse, mutect2, varscan2
- CFAP100 | c.1668G>T p.Q556H | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.286); catalogued as COSV61502766; called by muse, mutect2, varscan2
- CFAP46 | c.7939T>C p.S2647P | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.592); catalogued as COSV99584128; called by muse, varscan2
- CFAP70 | c.391C>T p.Q131* | Nonsense Mutation (SNP) | VAF 48/126 reads (38%) | catalogued as COSV60282234; called by muse, mutect2, varscan2
- CFAP74 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as rs201837422; called by mutect2, varscan2
- CFC1 | c.241G>T p.G81* | Nonsense Mutation (SNP) | VAF 93/505 reads (18%) | catalogued as COSV52090420; called by muse, mutect2, varscan2
- CFH | c.2488C>T p.R830W | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs62641696, COSV66408840; called by muse, mutect2, varscan2
- CGAS | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as rs1451835720, COSV100943634; called by muse, mutect2, varscan2
- CGNL1 | c.1772G>A p.R591Q | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs778457143, COSV55565656; called by muse, mutect2, varscan2
- CHAT | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as rs1475607266, COSV60322696; called by muse, mutect2, varscan2
- CHD7 | c.2612A>G p.E871G | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV101418046, COSV71113532; called by muse, mutect2, varscan2
- CHD8 | c.4948G>A p.A1650T (on ENST00000646647 / NM_001170629.2; = p.A1371T on NM_020920.4) | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as COSV100783807; called by muse, mutect2, varscan2
- CHMP6 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs913344986, COSV57327068; called by muse, mutect2, varscan2
- CHN1 | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 103/276 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs373546784; called by muse, mutect2, varscan2
- CHPF | c.1619C>T p.A540V | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.58); catalogued as rs778571617, COSV60534280; called by muse, mutect2, varscan2
- CHRD | c.310C>G p.P104A | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV52606900; called by muse, varscan2
- CHRNA1 | c.367del p.I123Ffs*67 (on ENST00000261007 / NM_001039523.3; = p.I98Ffs*67 on NM_000079.4) | Frame Shift Del (DEL) | VAF 80/254 reads (31%) | catalogued as rs753250273; called by mutect2, pindel, varscan2
- CHRNA4 | c.1432G>A p.V478M | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.309); catalogued as COSV64719005; called by muse, mutect2, varscan2
- CHRNB2 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.329); catalogued as rs527768017, COSV63808186; called by mutect2, varscan2
- CHST2 | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.146); catalogued as rs1296052640, COSV58885138; called by muse, mutect2, varscan2
- CHST3 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as rs1250555060, COSV64150771; called by muse, mutect2, varscan2
- CHSY3 | c.34G>A p.V12M | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1472041992, COSV59275353; called by muse, mutect2, varscan2
- CIC | c.2492C>T p.T831M | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV50546523; called by muse, mutect2, varscan2
- CIITA | c.1138C>T p.R380W | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as rs750567359, COSV60855892, COSV60856029; called by muse, mutect2, varscan2
- CISD2 | c.101C>T p.T34I | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.117); catalogued as COSV56765705; called by muse, mutect2, varscan2
- CIT | c.4534G>A p.E1512K | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs781056753, COSV55859602; called by muse, mutect2, varscan2
- CLCN6 | c.1834G>A p.V612I | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV56739138, COSV56742123; called by muse, mutect2, varscan2
- CLEC16A | c.383T>C p.V128A | Missense Mutation (SNP) | VAF 93/325 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV68498962; called by muse, mutect2, varscan2
- CLEC16A | c.2650G>A p.V884M | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as rs74163624, COSV55489300, COSV55490189; called by muse, mutect2, varscan2
- CLEC4M | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.983); catalogued as rs375821664; called by muse, mutect2, varscan2
- CLPTM1 | c.656A>G p.D219G | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as COSV61611594; called by muse, mutect2, varscan2
- CMTM8 | c.77G>A p.S26N | Missense Mutation (SNP) | VAF 66/181 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV56776532; called by muse, mutect2, varscan2
- CMTR2 | c.1798C>T p.R600* | Nonsense Mutation (SNP) | VAF 61/150 reads (41%) | catalogued as rs200221398, COSV57602756; called by muse, mutect2, varscan2
- CMTR2 | c.551T>G p.L184R | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.393); catalogued as COSV57603077; called by muse, mutect2
- CNBD1 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs747773867, COSV73072467; called by muse, mutect2, varscan2
- CNKSR1 | c.1535dup p.P513Tfs*9 (on ENST00000374253 / NM_001297647.2; = p.P506Tfs*9 on NM_006314.3) | Frame Shift Ins (INS) | VAF 23/83 reads (28%) | catalogued as rs753922055; called by mutect2, varscan2
- CNTN2 | c.1270G>A p.V424M | Missense Mutation (SNP) | VAF 61/185 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.222); catalogued as rs548252200, COSV59349297; called by muse, mutect2, varscan2
- CNTN6 | c.2678dup p.V894Sfs*25 | Frame Shift Ins (INS) | VAF 33/143 reads (23%) | catalogued as rs1415730148; called by mutect2, pindel, varscan2
- CNTNAP5 | c.194G>A p.G65D | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70480855; called by muse, mutect2, varscan2
- CNTNAP5 | c.2890G>A p.G964S | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.15); catalogued as rs776652801, COSV101443139; called by muse, mutect2, varscan2
- COL12A1 | c.8098G>A p.A2700T | Missense Mutation (SNP) | VAF 125/365 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779479987, COSV59392888, COSV59407435; called by muse, mutect2, varscan2
- COL22A1 | c.2014G>A p.G672S | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs756630962, COSV57324838; called by muse, mutect2, varscan2
- COL4A2 | c.5111G>A p.R1704H | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747313370, COSV64626923; called by muse, mutect2, varscan2
- COL4A3 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 143/409 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as rs773914532, COSV67414589; called by muse, mutect2, varscan2
- COL6A3 | c.3371C>T p.A1124V | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as rs374447921, COSV99799860; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- COL7A1 | c.8774G>A p.C2925Y | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56476299; called by muse, mutect2, varscan2
- COL7A1 | c.1277T>C p.L426P | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.977); catalogued as COSV60393634; called by muse, mutect2
- COMMD10 | c.58T>C p.S20P | Missense Mutation (SNP) | VAF 74/245 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV57235525; called by muse, varscan2
- COQ2 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 64/203 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.614); catalogued as COSV61021322; called by muse, mutect2, varscan2
- CORIN | c.2723T>A p.V908D | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99903102; called by muse, mutect2, varscan2
- CPQ | c.1016G>A p.G339D | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55142186; called by muse, mutect2, varscan2
- CPS1 | c.3462G>T p.E1154D | Missense Mutation (SNP) | VAF 116/302 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.801); catalogued as COSV51806479, COSV51812131; called by muse, mutect2, varscan2
- CPT1C | c.1160G>T p.R387M | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54918519; called by muse, mutect2, varscan2
- CPZ | c.769A>G p.M257V (on ENST00000360986 / NM_001014447.3; = p.M246V on NM_003652.3) | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV59922379; called by muse, mutect2, varscan2
- CREBBP | c.5204C>T p.T1735M | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs1064793090, CM104888, COSV52119093; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRISP1 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 159/408 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.521); catalogued as COSV100236661, COSV59993214; called by muse, mutect2, varscan2
- CRLF3 | c.1207C>T p.R403* | Nonsense Mutation (SNP) | VAF 81/205 reads (40%) | catalogued as COSV60835530; called by muse, mutect2, varscan2
- CRNN | c.1403A>G p.Q468R | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV55121445; called by muse, mutect2, varscan2
- CRY2 | c.1060A>G p.T354A | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101314560; called by muse, varscan2
- CRYBB1 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.32); catalogued as rs776964678, COSV53232899; called by muse, mutect2, varscan2
- CSF1 | c.205T>C p.F69L | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60032616; called by muse, mutect2, varscan2
- CSGALNACT2 | c.113C>T p.T38I | Missense Mutation (SNP) | VAF 24/444 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.198); catalogued as rs1398619438, COSV100989736; called by muse, mutect2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 40/130 reads (31%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CSRNP3 | c.1444C>T p.R482* | Nonsense Mutation (SNP) | VAF 64/169 reads (38%) | catalogued as rs199561929, COSV58776975, COSV58780852; called by muse, mutect2, varscan2
- CSTF2T | c.1325C>T p.A442V | Missense Mutation (SNP) | VAF 80/264 reads (30%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.022); catalogued as rs774154367, COSV58656456; called by muse, varscan2
- CTCFL | c.75del p.G26Afs*2 | Frame Shift Del (DEL) | VAF 57/209 reads (27%) | catalogued as rs1224759530; called by mutect2, pindel, varscan2
- CTIF | c.1417C>T p.R473C | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as rs775953061, COSV99837025; called by muse, mutect2, varscan2
- CTNNA2 | c.2659T>G p.S887A (on ENST00000402739 / NM_001282597.3; = p.S839A on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/191 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58144745; called by muse, mutect2, varscan2
- CTNND2 | c.2765A>G p.D922G | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV58875074; called by muse, mutect2, varscan2
- CTNND2 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs778030487, COSV58867380; called by muse, mutect2, varscan2
- CTR9 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 17/230 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV100797278; called by muse, mutect2
- CTR9 | c.1880G>A p.R627H | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs1413777307, COSV63728254; called by muse, varscan2
- CTR9 | c.2880_2882del p.R962del | In Frame Del (DEL) | VAF 52/156 reads (33%) | catalogued as rs968571283; called by pindel, varscan2
- CTXN3 | c.212T>C p.L71P | Missense Mutation (SNP) | VAF 67/254 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65218255; called by muse, mutect2
- CUTC | c.706C>T p.R236* | Nonsense Mutation (SNP) | VAF 38/126 reads (30%) | catalogued as rs867595661, COSV65081673; called by muse, mutect2, varscan2
- CUX2 | c.3121G>A p.V1041M | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs755408839, COSV55628672; called by muse, mutect2, varscan2
- CXCR2 | c.993A>G p.I331M | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV59280287; called by muse, mutect2, varscan2
- CXCR3 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.058); catalogued as rs905571589, COSV65461770; called by muse, mutect2, varscan2
- CYLC1 | c.468T>G p.N156K | Missense Mutation (SNP) | VAF 123/385 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.401); catalogued as COSV61411169; called by muse, mutect2, varscan2
- CYP17A1 | c.1486C>T p.R496C | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1250463562, CM920226, COSV64004840; called by muse, mutect2, varscan2
- CYP27B1 | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768857789, COSV56984418; called by muse, mutect2, varscan2
- CYP2D6 | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 79/224 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs979622353, COSV100637255; called by muse, varscan2
- CYP7B1 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 92/233 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1410531135, COSV59584668, COSV59594434; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYSLTR1 | c.697G>T p.G233* | Nonsense Mutation (SNP) | VAF 136/447 reads (30%) | catalogued as COSV64819797, COSV64820875; called by muse, varscan2
- DAAM1 | c.1488G>T p.K496N | Missense Mutation (SNP) | VAF 81/237 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV62835380; called by muse, mutect2, varscan2
- DBX2 | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.198); catalogued as COSV100224224; called by muse, mutect2
- DCAF12L2 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775259004, COSV63580943; called by muse, mutect2, varscan2
- DCAF12L2 | c.126G>T p.Q42H | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.188); catalogued as COSV63580954; called by muse, mutect2, varscan2
- DCAF5 | c.2468G>T p.R823M | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV58459583; called by muse, mutect2, varscan2
- DCLRE1C | c.207_209del p.L70del | In Frame Del (DEL) | VAF 92/288 reads (32%) | catalogued as rs753202682; called by pindel, varscan2
- DCST1 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1281341389, COSV55057752; called by muse, mutect2, varscan2
- DCTN1 | c.3518G>A p.R1173H | Missense Mutation (SNP) | VAF 79/202 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs980920477, COSV62620128; called by muse, mutect2, varscan2
- DCUN1D1 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 88/259 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.084); catalogued as rs1315990525, COSV53044104; called by muse, mutect2, varscan2
- DDB1 | c.685dup p.A229Gfs*15 | Frame Shift Ins (INS) | VAF 36/92 reads (39%) | catalogued as rs757472327; called by mutect2, varscan2
- DDIT4L | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs183155282; called by muse, mutect2, varscan2
- DDX11 | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 104/387 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as rs148220883, COSV52502131; called by muse, mutect2, varscan2
- DDX11 | c.1862del p.G621Vfs*32 | Frame Shift Del (DEL) | VAF 19/173 reads (11%) | catalogued as rs766120336; called by mutect2, pindel, varscan2
- DDX11 | c.2170G>T p.G724C | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52502163, COSV99298823; called by muse, mutect2, varscan2
- DDX54 | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs201173369, COSV58372759; called by muse, mutect2, varscan2
- DDX55 | c.239dup p.S81Efs*48 | Frame Shift Ins (INS) | VAF 25/89 reads (28%) | catalogued as rs762423517; called by mutect2, pindel, varscan2
- DDX59 | c.1294A>G p.K432E | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV58751329; called by muse, varscan2
- DERA | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as COSV70774025; called by muse, mutect2, varscan2
- DES | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.874); catalogued as COSV64660147; called by muse, mutect2, varscan2
- DGKD | c.2564del p.G855Vfs*48 (on ENST00000264057 / NM_152879.3; = p.G811Vfs*48 on NM_003648.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | catalogued as rs35538077; called by mutect2, pindel, varscan2
- DGKK | c.371A>C p.E124A | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV101052907; called by muse, mutect2
- DGKZ | c.726C>T p.L242= | Splice Region (SNP) | VAF 3/9 reads (33%) | catalogued as rs1192074707; called by muse, mutect2
- DHX34 | c.2686G>A p.V896I | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.218); catalogued as rs756746132, COSV60894984; called by muse, mutect2, varscan2
- DHX37 | c.1136T>C p.V379A | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.142); catalogued as COSV58133347; called by muse, mutect2
- DIAPH1 | c.2108del p.P703Hfs*65 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | catalogued as rs771360300; called by mutect2, varscan2
- DIP2B | c.4471G>A p.A1491T | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.07); catalogued as rs777261445, COSV56581591; called by muse, mutect2, varscan2
- DISP2 | c.151A>C p.S51R | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.996); catalogued as rs750749839, COSV99139759; called by muse, mutect2
- DKK1 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138915253; called by muse, mutect2, varscan2
- DLGAP3 | c.2185C>T p.R729C | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs142976280; called by muse, mutect2, varscan2
- DLGAP3 | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.076); catalogued as rs777868236, COSV52396105; called by muse, mutect2, varscan2
- DLK1 | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs767836232, COSV57991140; called by muse, mutect2, varscan2
- DLST | c.277G>A p.V93I | Missense Mutation (SNP) | VAF 74/245 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV99471827; called by muse, mutect2, varscan2
- DLX2 | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 72/212 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200908537, COSV52231832, COSV52232028; called by muse, mutect2, varscan2
- DMAP1 | c.904C>G p.P302A | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0.023); catalogued as COSV60000305; called by muse, mutect2, varscan2
- DMXL2 | c.2972T>C p.I991T | Missense Mutation (SNP) | VAF 82/193 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV51843626; called by muse, mutect2, varscan2
- DMXL2 | c.2512G>A p.A838T | Missense Mutation (SNP) | VAF 64/214 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.454); catalogued as rs199866251; called by muse, mutect2, varscan2
- DNAH10 | c.8734A>G p.I2912V (on ENST00000409039; = p.I2851V on NM_207437.3) | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV68991111; called by muse, mutect2, varscan2
- DNAH17 | c.6347A>G p.E2116G | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101101650; called by muse, mutect2, varscan2
- DNAH2 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.31); catalogued as rs768754911, COSV50015282; called by muse, mutect2, varscan2
- DNAH2 | c.12917G>A p.S4306N | Missense Mutation (SNP) | VAF 70/178 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV66718269; called by muse, varscan2
- DNAH5 | c.12829T>C p.F4277L | Missense Mutation (SNP) | VAF 86/241 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.282); catalogued as COSV54216036; called by muse, mutect2, varscan2
- DNAH7 | c.4181C>T p.A1394V | Missense Mutation (SNP) | VAF 100/280 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56758708; called by muse, mutect2, varscan2
- DNAH8 | c.4837G>T p.D1613Y | Missense Mutation (SNP) | VAF 107/376 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59436372; called by muse, mutect2, varscan2
- DNAH8 | c.4838A>T p.D1613V | Missense Mutation (SNP) | VAF 107/375 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59436397, COSV59438542; called by muse, mutect2, varscan2
- DNAH8 | c.9197G>A p.R3066H | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs540958336, COSV100543719; called by muse, mutect2, varscan2
- DNAH9 | c.7111G>T p.E2371* | Nonsense Mutation (SNP) | VAF 55/161 reads (34%) | catalogued as COSV52343834, COSV52380747; called by muse, mutect2, varscan2
- DNM2 | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as COSV99139013; called by muse, mutect2, varscan2
- DNTTIP1 | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs767661063, COSV54755204; called by muse, mutect2, varscan2
- DOCK7 | c.2765A>C p.K922T | Missense Mutation (SNP) | VAF 55/157 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as COSV52001321; called by muse, mutect2
- DOK4 | c.190A>G p.N64D | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as COSV99538238; called by muse, mutect2, varscan2
- DPT | c.382T>C p.W128R | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199993492, COSV63189759; called by muse, mutect2, varscan2
- DPYD | c.1010T>C p.V337A | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV64594413; called by muse, mutect2, varscan2
- DPYSL2 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.222); catalogued as rs751569597, COSV60785726; called by muse, mutect2, varscan2
- DPYSL5 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 65/176 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as rs747513449, COSV56510456; called by muse, mutect2, varscan2
- DSCAML1 | c.1565C>T p.S522L (on ENST00000321322; = p.S462L on NM_020693.4) | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.396); catalogued as rs935338538, COSV58387224; called by muse, mutect2, varscan2
- DSEL | c.970T>C p.F324L | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs745761044, COSV59490524; called by muse, mutect2, varscan2
- DST | c.3860G>A p.G1287D (on ENST00000361203 / NM_001374722.1; = p.G961D on NM_001723.6) | Missense Mutation (SNP) | VAF 92/260 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as rs770079828, COSV55006966; called by muse, varscan2
- DSTYK | c.938T>C p.L313P | Missense Mutation (SNP) | VAF 66/158 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65686031; called by muse, mutect2, varscan2
- DUOX2 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1293606333, COSV100545778; called by muse, mutect2, varscan2
- DYNC2I1 | c.2887T>C p.S963P | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV101337620; called by mutect2, varscan2
- DYRK1B | c.1633del p.Q545Sfs*19 | Frame Shift Del (DEL) | VAF 10/25 reads (40%) | catalogued as rs775499198; called by mutect2, pindel, varscan2
- DYSF | c.2263G>A p.A755T | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50476650, COSV99245007; called by muse, mutect2, varscan2
- EBF3 | c.1374C>T p.V458= (on ENST00000355311 / NM_001375392.1; = p.V449= on NM_001005463.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 14/43 reads (33%) | catalogued as rs751553455, COSV100799071; called by muse, mutect2, varscan2
- ECEL1 | c.665T>C p.V222A | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs766643692, COSV100458510; called by mutect2, varscan2
- ECI1 | c.574A>G p.T192A | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs1567312880, COSV57043246; called by muse, mutect2
- ECM1 | c.1045T>C p.C349R | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777173556, COSV60871768; called by muse, mutect2
- EEA1 | c.300+2T>C p.X100_splice | Splice Site (SNP) | VAF 215/553 reads (39%) | catalogued as COSV59284236; called by muse, mutect2, varscan2
- EEF1A2 | c.391G>A p.G131R | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.5); catalogued as COSV53205531; called by muse, mutect2, varscan2
- EEF1AKMT4 | c.538dup p.H180Pfs*68 | Frame Shift Ins (INS) | VAF 37/128 reads (29%) | catalogued as rs751055758; called by mutect2, pindel, varscan2
- EFCAB5 | c.450dup p.L151Tfs*3 | Frame Shift Ins (INS) | VAF 34/131 reads (26%) | catalogued as rs760813779; called by mutect2, varscan2
- EFCAB5 | c.3746C>T p.T1249M | Missense Mutation (SNP) | VAF 91/247 reads (37%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.921); catalogued as rs781519608, COSV57927106; called by muse, mutect2, varscan2
- EGFLAM | c.2405G>T p.R802M | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.641); catalogued as COSV59297661; called by muse, mutect2, varscan2
- EIF4G1 | c.19T>C p.S7P | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100071554; called by mutect2, varscan2
- ELOF1 | c.227A>G p.D76G | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52947415, COSV52947587; called by muse, mutect2, varscan2
- EMILIN2 | c.1307G>A p.R436H | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs201232565, COSV54422496; called by muse, mutect2, varscan2
- EML1 | c.2176G>C p.G726R | Missense Mutation (SNP) | VAF 89/290 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV51743194; called by muse, mutect2
- EMP3 | c.398del p.G133Afs*? | Frame Shift Del (DEL) | VAF 14/47 reads (30%) | catalogued as rs1275937883; called by mutect2, pindel, varscan2
- EMSY | c.244A>G p.N82D | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.013); catalogued as COSV58258875; called by muse, mutect2, varscan2
- ENO1 | c.326A>G p.N109S | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV52303331; called by muse, mutect2, varscan2
- EOGT | c.808G>A p.V270M | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs1359276220, COSV55150256; called by muse, mutect2, varscan2
- EPB41L5 | c.1819C>T p.P607S | Missense Mutation (SNP) | VAF 64/224 reads (29%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as COSV55350446; called by muse, mutect2, varscan2
- EPHA5 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.01); catalogued as COSV99896950; called by muse, mutect2, varscan2
- EPN1 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs754608786, COSV50036384, COSV99321587; called by muse, mutect2, varscan2
- EPN1 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV50036400; called by muse, mutect2, varscan2
- EPN1 | c.1068T>C p.G356= (on ENST00000270460 / NM_001321263.1; = p.G331= on NM_013333.3) | Splice Region (SNP) | VAF 29/82 reads (35%) | catalogued as COSV50036412; called by muse, mutect2
- EPRS1 | c.2312A>T p.K771I | Missense Mutation (SNP) | VAF 59/186 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV65098220; called by muse, mutect2, varscan2
- EPRS1 | c.1468G>A p.D490N | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as COSV65098224; called by muse, mutect2, varscan2
- ERAP2 | c.1413G>T p.E471D | Missense Mutation (SNP) | VAF 78/246 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as COSV65939300; called by muse, varscan2
- ERCC3 | c.1469A>G p.E490G | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV53426494; called by muse, mutect2, varscan2
- ERCC6 | c.3042G>T p.Q1014H | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.199); catalogued as COSV63388967; called by muse, mutect2, varscan2
- ERICH3 | c.2773G>A p.A925T | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV58603424; called by muse, mutect2, varscan2
- ERN1 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.196); catalogued as COSV70501329; called by muse, mutect2, varscan2
- ESPL1 | c.3583G>A p.A1195T | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200640004, COSV57758575; called by muse, mutect2, varscan2
- ESR1 | c.240del p.Y80* | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | catalogued as COSV52786512; called by mutect2, pindel, varscan2
- ETF1 | c.913G>A p.V305I | Missense Mutation (SNP) | VAF 87/217 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs1286502948, COSV62127197; called by muse, mutect2, varscan2
- ETFB | c.506del p.G169Afs*7 | Frame Shift Del (DEL) | VAF 17/75 reads (23%) | catalogued as COSV100164273, COSV58536345; called by mutect2, varscan2
- EVC2 | c.2951C>A p.A984D | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.416); catalogued as COSV60390836; called by muse, mutect2, varscan2
- EXOC1 | c.668A>C p.E223A | Missense Mutation (SNP) | VAF 138/408 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0.019); catalogued as COSV62119754; called by muse, mutect2
- EXOC1 | c.2470G>T p.G824C | Missense Mutation (SNP) | VAF 92/240 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62119766, COSV62121624; called by muse, mutect2, varscan2
- EXOC3L4 | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | catalogued as COSV101197566; called by muse, mutect2, varscan2
- EXOC7 | c.878G>A p.G293D | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as COSV58740762; called by muse, mutect2, varscan2
- EXOSC10 | c.1904C>A p.A635E | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100442233; called by muse, mutect2, varscan2
- EXOSC5 | c.516G>T p.K172N | Missense Mutation (SNP) | VAF 14/185 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.162); catalogued as COSV55370838; called by muse, mutect2
- EYA3 | c.1505T>C p.F502S | Missense Mutation (SNP) | VAF 106/307 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65816203; called by muse, mutect2, varscan2
- EYA3 | c.296T>C p.L99P | Missense Mutation (SNP) | VAF 208/583 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65816211; called by muse, varscan2
- EZR | c.1439C>A p.P480Q | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.044); catalogued as COSV99791640; called by muse, mutect2, varscan2
- F8 | c.3287T>A p.V1096D | Missense Mutation (SNP) | VAF 24/601 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100811307; called by muse, mutect2
- FAHD2A | c.98G>T p.R33L | Missense Mutation (SNP) | VAF 110/294 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs766633125, COSV51977897; called by muse, mutect2, varscan2
- FAM111B | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV59111463, COSV59111530; called by muse, mutect2, varscan2
- FAM120B | c.1909T>C p.C637R | Missense Mutation (SNP) | VAF 78/238 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.101); catalogued as rs1438590515, COSV53002727; called by muse, mutect2
- FAM135B | c.3887T>C p.L1296P | Missense Mutation (SNP) | VAF 68/217 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52716352; called by muse, mutect2, varscan2
- FAM13A | c.3046A>T p.R1016* | Nonsense Mutation (SNP) | VAF 53/152 reads (35%) | catalogued as COSV52000205; called by muse, mutect2, varscan2
- FAM167B | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100405257; called by muse, varscan2
- FAM187B | c.709G>T p.G237* | Nonsense Mutation (SNP) | VAF 65/167 reads (39%) | catalogued as COSV61201127; called by muse, mutect2, varscan2
- FAM193A | c.2012C>T p.A671V | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV61191975; called by muse, mutect2, varscan2
- FAM193A | c.2497del p.M833Wfs*23 | Frame Shift Del (DEL) | VAF 48/142 reads (34%) | catalogued as rs768952789; called by mutect2, varscan2
- FAM20B | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 113/283 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs772062570, COSV55379766; called by muse, mutect2, varscan2
- FAM20C | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.78); PolyPhen benign (0.038); catalogued as rs931803647, COSV58232801; called by muse, mutect2, varscan2
- FAM47C | c.599del p.P200Rfs*625 | Frame Shift Del (DEL) | VAF 20/75 reads (27%) | catalogued as COSV63726734; called by mutect2, pindel, varscan2
- FAM53C | c.1093C>T p.R365W | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs777338677, COSV53511210; called by muse, mutect2, varscan2
- FAM83D | c.1543del p.H515Tfs*6 | Frame Shift Del (DEL) | VAF 37/124 reads (30%) | catalogued as rs754952124; called by mutect2, pindel, varscan2
- FAM83H | c.1774G>A p.G592S | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs1230011427, COSV66353684; called by muse, mutect2, varscan2
- FANCI | c.2115A>G p.I705M | Missense Mutation (SNP) | VAF 124/348 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV55525365; called by muse, mutect2, varscan2
- FAP | c.1813A>G p.R605G | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV51860712; called by muse, mutect2
- FAR1 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 132/305 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.211); catalogued as rs753671320, COSV61384504; called by muse, mutect2, varscan2
- FASN | c.6553C>T p.R2185W | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs372065783; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FASTKD2 | c.483G>T p.E161D | Missense Mutation (SNP) | VAF 58/193 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV52697865; called by muse, mutect2, varscan2
- FAT4 | c.1349C>T p.A450V | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.189); catalogued as COSV67883720; called by muse, mutect2, varscan2
- FAT4 | c.10529C>A p.P3510H | Missense Mutation (SNP) | VAF 85/202 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58678612; called by muse, mutect2, varscan2
- FBF1 | c.1525A>G p.T509A (on ENST00000586717; = p.T523A on NM_001319193.1) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59864277; called by muse, mutect2, varscan2
- FBLN2 | c.3362T>G p.I1121S | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55482760; called by muse, mutect2, varscan2
- FBN2 | c.5111G>T p.G1704V | Missense Mutation (SNP) | VAF 71/211 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52505120; called by muse, mutect2, varscan2
- FBN3 | c.5293G>A p.D1765N | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.03); catalogued as rs759106137, COSV54452904; called by muse, mutect2, varscan2
- FBN3 | c.2542C>T p.R848C | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.765); catalogued as rs571909633, COSV54457414; called by muse, mutect2, varscan2
- FBXL19 | c.614del p.P205Rfs*26 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | catalogued as rs745385709; called by mutect2, varscan2
- FBXO15 | c.1516T>C p.F506L | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.311); catalogued as COSV99503119; called by muse, mutect2, varscan2
- FBXO24 | c.805A>T p.I269F (on ENST00000241071 / NM_033506.3; = p.I307F on NM_012172.5) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV99575059; called by muse, mutect2, varscan2
- FBXW2 | c.753A>C p.K251N | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1221663608, COSV61596717; called by muse, mutect2, varscan2
- FCGRT | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.63); catalogued as COSV55529194; called by muse, mutect2, varscan2
- FCRL3 | c.1436C>T p.T479I | Missense Mutation (SNP) | VAF 77/212 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.897); catalogued as COSV63840587; called by muse, mutect2, varscan2
- FERMT3 | c.271C>A p.L91I | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1003429411, COSV54178341; called by muse, mutect2, varscan2
- FFAR4 | c.911T>C p.L304P | Missense Mutation (SNP) | VAF 128/425 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65159881; called by muse, mutect2
- FGD6 | c.3094A>G p.N1032D | Missense Mutation (SNP) | VAF 46/239 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59691886; called by muse, mutect2, varscan2
- FGF13 | c.574G>T p.A192S | Missense Mutation (SNP) | VAF 252/761 reads (33%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.469); catalogued as COSV59544278; called by muse, mutect2, varscan2
- FGFR4 | c.2167C>T p.R723C | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs201490532, COSV52802140; called by muse, mutect2, varscan2
- FIBCD1 | c.1259A>G p.N420S | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53392988; called by muse, mutect2, varscan2
- FITM2 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.04); catalogued as rs370245406; called by muse, mutect2, varscan2
- FJX1 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV100502617; called by muse, mutect2, varscan2
- FLI1 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55643674; called by muse, mutect2, varscan2
- FLNA | c.3353G>T p.G1118V | Missense Mutation (SNP) | VAF 59/191 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV61040689; called by muse, mutect2, varscan2
- FLNC | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs778751919, COSV57953517; called by muse, mutect2, varscan2
- FLYWCH1 | c.1688G>A p.R563H (on ENST00000253928 / NM_001308068.2; = p.R562H on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs780119016, COSV54146729, COSV99558613; called by mutect2, varscan2
- FMN2 | c.2246C>T p.T749M | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs371967368, COSV60425593; called by muse, mutect2, varscan2
- FOSB | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); catalogued as rs764116136; called by mutect2, varscan2
- FPGT | c.1657A>C p.T553P | Missense Mutation (SNP) | VAF 85/262 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.309); catalogued as COSV63837479; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1161del p.L388Yfs*25 | Frame Shift Del (DEL) | VAF 69/271 reads (25%) | catalogued as rs1291679708, COSV100437911; called by mutect2, pindel, varscan2
- FRAS1 | c.2098A>G p.R700G | Missense Mutation (SNP) | VAF 62/202 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV53601550; called by muse, mutect2, varscan2
- FRMD6 | c.904T>C p.Y302H (on ENST00000344768 / NM_001267046.2; = p.Y294H on NM_152330.4) | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61087285; called by muse, mutect2, varscan2
- FRY | c.1840C>T p.R614* | Nonsense Mutation (SNP) | VAF 59/168 reads (35%) | catalogued as rs776773297, COSV66567927; called by muse, mutect2, varscan2
- FSCN2 | c.593G>A p.G198D | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100603243; called by muse, mutect2, varscan2
- FSIP2 | c.18980A>C p.D6327A | Missense Mutation (SNP) | VAF 68/177 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58082673; called by muse, mutect2, varscan2
- FSTL4 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs200915266, COSV54767571; called by muse, mutect2, varscan2
- FURIN | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51575836; called by muse, mutect2, varscan2
- FUT1 | c.461A>G p.Y154C | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM973075, COSV59567934; called by muse, mutect2, varscan2
- FZD1 | c.341G>A p.G114D | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.609); catalogued as rs751566731, COSV55309825; called by muse, varscan2
- FZD1 | c.440G>A p.G147D | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55309837; called by muse, varscan2
- GAB3 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 74/206 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1557257611, COSV65819365; called by muse, varscan2
- GALC | c.1888T>C p.Y630H | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.031); catalogued as CD972224, COSV54324432; called by muse, mutect2, varscan2
- GALNT10 | c.1319C>T p.T440M | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.129); catalogued as rs147745456; called by mutect2, varscan2
- GALNTL6 | c.879del p.I294Sfs*41 | Frame Shift Del (DEL) | VAF 29/112 reads (26%) | catalogued as COSV101560007; called by mutect2, pindel, varscan2
- GALR1 | c.520C>T p.Q174* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | catalogued as COSV55316569; called by muse, mutect2, varscan2
- GAN | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 76/208 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.365); catalogued as rs574374537, COSV73720739, COSV73720828; called by muse, varscan2
- GATA3 | c.944C>T p.T315M | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CD003632, COSV60517092; called by muse, mutect2, varscan2
- GATAD2A | c.1721C>A p.A574D | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as COSV53068344; called by muse, mutect2, varscan2
- GATAD2B | c.91C>T p.R31* | Nonsense Mutation (SNP) | VAF 50/140 reads (36%) | catalogued as COSV64083769; called by muse, mutect2, varscan2
- GBA2 | c.1159G>T p.G387C | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV62305537; called by muse, mutect2, varscan2
- GBA3 | c.1042G>A p.V348M | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.369); catalogued as rs915467565, COSV101545482; called by muse, mutect2, varscan2
- GCM1 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs764579596, COSV52521405; called by muse, mutect2, varscan2
- GDA | c.880C>T p.R294* | Nonsense Mutation (SNP) | VAF 35/97 reads (36%) | catalogued as COSV52993755; called by muse, mutect2, varscan2
- GDAP1 | c.886G>A p.V296I | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0.052); catalogued as COSV55185302; called by muse, mutect2, varscan2
- GDF5 | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs763209567, COSV65500436; called by muse, mutect2, varscan2
- GDPD5 | c.790A>G p.T264A | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV61127014; called by muse, mutect2, varscan2
- GET4 | c.542A>G p.E181G | Missense Mutation (SNP) | VAF 99/265 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56253638; called by muse, varscan2
- GFRA1 | c.832C>A p.L278I | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.807); catalogued as COSV62604350; called by muse, mutect2, varscan2
- GGA2 | c.910A>G p.T304A | Missense Mutation (SNP) | VAF 64/220 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV59168023; called by muse, mutect2
- GIGYF1 | c.331del p.L111Wfs*234 | Frame Shift Del (DEL) | VAF 28/71 reads (39%) | catalogued as rs763147690; called by mutect2, varscan2
- GIGYF2 | c.1455A>T p.E485D | Missense Mutation (SNP) | VAF 73/239 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs547560862, COSV65248087; called by muse, mutect2, varscan2
- GJA10 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV65354722; called by muse, mutect2, varscan2
- GLB1 | c.10T>C p.F4L | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV56562750; called by muse, mutect2, varscan2
- GLB1L3 | c.1627A>G p.T543A | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV68392548; called by muse, mutect2, varscan2
- GLRA2 | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 209/537 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54338753; called by muse, mutect2, varscan2
- GMPPA | c.1195A>G p.I399V | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as COSV58006524; called by muse, mutect2
- GNE | c.1862A>G p.Y621C (on ENST00000396594 / NM_001128227.3; = p.Y590C on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as rs1363913351, COSV64951577; called by muse, mutect2, varscan2
- GNG12 | c.202dup p.T68Nfs*9 | Frame Shift Ins (INS) | VAF 48/173 reads (28%) | catalogued as rs1022402829; called by mutect2, varscan2
- GOLGA3 | c.3824A>C p.Q1275P | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as COSV99202324; called by muse, mutect2
- GOLGA4 | c.14T>C p.L5P | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57887342; called by muse, mutect2, varscan2
- GPR4 | c.428C>A p.A143D | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.828); catalogued as rs1303575895, COSV59916559; called by muse, mutect2, varscan2
- GPSM1 | c.770A>G p.N257S | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100696560; called by muse, mutect2, varscan2
- GRB10 | c.1411A>G p.I471V (on ENST00000398812; = p.I425V on NM_001001549.3) | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV60009192; called by muse, mutect2
- GREB1 | c.1664G>A p.S555N | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV52184163, COSV52185751; called by muse, mutect2, varscan2
- GRIK1 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 137/227 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs539327767, COSV58710129; called by muse, mutect2, varscan2
- GRK2 | c.662G>A p.C221Y | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV57951259; called by muse, mutect2, varscan2
- GRM6 | c.1295C>T p.A432V | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.066); catalogued as rs377276357; called by muse, mutect2, varscan2
- GRM7 | c.2099C>A p.T700K | Missense Mutation (SNP) | VAF 124/401 reads (31%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.991); catalogued as rs752445160, COSV63137545, COSV63161207; called by muse, mutect2, varscan2
- GRM8 | c.1707C>A p.C569* | Nonsense Mutation (SNP) | VAF 35/113 reads (31%) | catalogued as COSV58816588; called by muse, mutect2, varscan2
- GTF3C1 | c.2027G>A p.R676Q | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs1345925592, COSV62239081; called by muse, mutect2, varscan2
- GUF1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 17/57 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.38); catalogued as COSV55782091; called by muse, mutect2, varscan2
- H1-5 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 128/389 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1207966785, COSV58899627; called by muse, mutect2, varscan2
- H2BC13 | c.251A>G p.Y84C | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV62440465; called by muse, mutect2, varscan2
- H2BC4 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.148); catalogued as rs942484360, COSV58415514; called by muse, mutect2, varscan2
- HAUS3 | c.1075C>T p.Q359* | Nonsense Mutation (SNP) | VAF 93/335 reads (28%) | catalogued as COSV54722380; called by muse, mutect2, varscan2
- HBS1L | c.1843C>T p.R615* | Nonsense Mutation (SNP) | VAF 92/232 reads (40%) | catalogued as CM1311869, COSV63200929; called by muse, mutect2, varscan2
- HCFC1 | c.2822C>T p.A941V | Missense Mutation (SNP) | VAF 68/171 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.956); catalogued as COSV60071094; called by muse, mutect2, varscan2
- HCN4 | c.766C>T p.H256Y | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56082543; called by muse, mutect2, varscan2
- HDAC4 | c.2703dup p.M902Hfs*5 | Frame Shift Ins (INS) | VAF 8/16 reads (50%) | catalogued as rs747537946; called by mutect2, varscan2
- HEATR5A | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV66339523; called by muse, mutect2, varscan2
- HECTD4 | c.13100del p.P4367Qfs*21 | Frame Shift Del (DEL) | VAF 35/90 reads (39%) | catalogued as rs746492036; called by mutect2, pindel, varscan2
- HERC1 | c.3506C>T p.T1169I | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.309); catalogued as COSV71247051; called by muse, mutect2, varscan2
- HES4 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766490059, COSV59242081; called by muse, mutect2, varscan2
- HIC2 | c.686del p.G229Afs*45 | Frame Shift Del (DEL) | VAF 31/102 reads (30%) | catalogued as rs1218980629; called by mutect2, pindel, varscan2
- HID1 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs746182882, COSV100585947; called by muse, varscan2
- HK1 | c.2326C>A p.L776M | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1054203; called by muse, mutect2, varscan2
- HK3 | c.2138T>C p.M713T | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0.022); catalogued as COSV52838506; called by muse, mutect2, varscan2
- HLA-A | c.155T>C p.V52A | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV65139169; called by muse, mutect2
- HLA-B | c.240del p.P81Rfs*70 | Frame Shift Del (DEL) | VAF 91/203 reads (45%) | catalogued as COSV69521421; called by mutect2, pindel, varscan2
- HLA-C | c.425A>C p.Y142S | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV66111908; called by muse, varscan2
- HLA-DRA | c.607T>C p.W203R | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV66622653; called by muse, mutect2
- HMG20B | c.340A>G p.T114A | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs762900877, COSV99502985; called by muse, mutect2, varscan2
- HMGB4 | c.448A>G p.R150G | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV53898856; called by muse, mutect2, varscan2
- HMMR | c.709A>G p.I237V | Missense Mutation (SNP) | VAF 143/357 reads (40%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as rs1187765108, COSV62374244; called by muse, mutect2
- HNF1A | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs760640415, COSV57461054; called by muse, varscan2
- HOXC9 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777643587, COSV57716328; called by muse, mutect2, varscan2
- HPN | c.908-1G>T p.X303_splice | Splice Site (SNP) | VAF 16/38 reads (42%) | catalogued as COSV52883050; called by muse, mutect2, varscan2
- HRH2 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51573559; called by muse, mutect2, varscan2
- HS6ST2 | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 54/118 reads (46%) | catalogued as rs1456848709, COSV63711933; called by muse, mutect2, varscan2
- HSPA2 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as COSV55969203; called by muse, mutect2, varscan2
- HSPA4L | c.2167-2A>G p.X723_splice | Splice Site (SNP) | VAF 39/104 reads (38%) | catalogued as COSV99612664; called by muse, varscan2
- HSPB1 | c.241C>A p.L81I | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV50349125; called by muse, mutect2, varscan2
- HTRA4 | c.956C>A p.A319D | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56758150, COSV56758986; called by muse, mutect2, varscan2
- HUWE1 | c.11987T>C p.V3996A | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as COSV53340727; called by muse, mutect2, varscan2
- HVCN1 | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs781358524, COSV54371702; called by muse, mutect2, varscan2
- HYDIN | c.9224G>A p.R3075H | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs569134886, COSV59253771; called by muse, mutect2, varscan2
- HYDIN | c.7544G>A p.R2515H | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs776395603, COSV59253798; called by muse, mutect2, varscan2
- HYDIN | c.4361T>C p.V1454A | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV101141474; called by muse, mutect2, varscan2
- IARS2 | c.1513T>G p.S505A | Missense Mutation (SNP) | VAF 101/307 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as COSV56958808; called by muse, mutect2, varscan2
- ICAM5 | c.895C>T p.Q299* | Nonsense Mutation (SNP) | VAF 11/50 reads (22%) | catalogued as COSV99703178; called by muse, mutect2, varscan2
- IER3IP1 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 91/234 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV56505930; called by muse, varscan2
- IFRD2 | c.386A>G p.D129G | Missense Mutation (SNP) | VAF 86/199 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV57113195; called by muse, mutect2, varscan2
- IFT140 | c.101A>G p.Y34C | Missense Mutation (SNP) | VAF 54/184 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.428); catalogued as COSV68487314; called by muse, mutect2, varscan2
- IFT80 | c.893T>C p.V298A | Missense Mutation (SNP) | VAF 60/179 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as COSV58446556; called by muse, mutect2
- IGFN1 | c.3406del p.R1136Gfs*8 (on ENST00000295591 / NM_001367841.1; = p.R3593Gfs*8 on NM_001164586.2) | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | catalogued as rs774748743; called by mutect2, pindel, varscan2
- IGHMBP2 | c.1129T>C p.C377R | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1409138201, COSV54821549; called by muse, mutect2
- IGSF1 | c.2588C>A p.P863H | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63836854; called by muse, mutect2, varscan2
- IGSF21 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1378720517, COSV52129911, COSV52131696; called by muse, mutect2, varscan2
- IGSF9 | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as rs950811935, COSV63639516; called by muse, mutect2, varscan2
- IL13RA1 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 85/262 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as rs141752835, COSV65426258; called by muse, mutect2, varscan2
- IL13RA2 | c.1141T>C p.*381Rext*23 | Nonstop Mutation (SNP) | VAF 260/799 reads (33%) | catalogued as rs1556506999, COSV54564664; called by muse, mutect2
- IL27RA | c.1270C>T p.R424* | Nonsense Mutation (SNP) | VAF 33/79 reads (42%) | catalogued as rs746755376, COSV54599991; called by muse, mutect2, varscan2
- ILDR2 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs748481777, COSV54831741; called by muse, mutect2, varscan2
- IMMP2L | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as COSV59227710; called by muse, mutect2, varscan2
- ING5 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 134/349 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV57978372; called by muse, mutect2, varscan2
- INPP1 | c.1160T>C p.L387P | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.054); catalogued as COSV59415526; called by muse, mutect2, varscan2
- INTS1 | c.2063C>T p.A688V | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.047); catalogued as rs367966750; called by muse, mutect2, varscan2
- INTS6L | c.2221G>T p.G741* | Nonsense Mutation (SNP) | VAF 152/420 reads (36%) | catalogued as COSV66084068; called by muse, mutect2, varscan2
- IQGAP1 | c.3631C>A p.L1211M | Missense Mutation (SNP) | VAF 100/282 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs535117997, COSV51583414; called by muse, mutect2, varscan2
- IQGAP3 | c.1298G>A p.G433D | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV63250510; called by muse, mutect2, varscan2
- IQSEC2 | c.1849C>T p.R617C (on ENST00000642864 / NM_001111125.3; = p.R412C on NM_015075.2) | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.742); catalogued as rs1556863213, COSV64724638; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IQSEC3 | c.2423A>T p.D808V (on ENST00000538872 / NM_001170738.2; = p.D505V on NM_015232.1) | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV58283126; called by muse, mutect2, varscan2
- IRAG1 | c.671G>A p.G224D | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV70210523; called by muse, mutect2, varscan2
- IRF3 | c.346G>T p.D116Y | Missense Mutation (SNP) | VAF 67/190 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.647); catalogued as COSV55862821; called by muse, mutect2, varscan2
- IRS4 | c.1754G>A p.G585D | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.915); catalogued as COSV64533201; called by muse, mutect2, varscan2
- IRX4 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs1278591541, COSV51471877; called by muse, mutect2, varscan2
- IRX6 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as rs371123518; called by muse, mutect2, varscan2
- ISOC2 | c.293G>T p.R98L | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV50034901; called by muse, mutect2, varscan2
- ITGA1 | c.155A>G p.Q52R | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV99250823; called by muse, mutect2
- ITGA1 | c.2854T>C p.F952L | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.23); catalogued as COSV50879119; called by muse, mutect2, varscan2
- ITGA2 | c.3265T>C p.F1089L | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); catalogued as COSV56858289; called by muse, mutect2, varscan2
- ITGB2 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs374031101; called by muse, mutect2, varscan2
- ITPR1 | c.7027C>T p.R2343* (on ENST00000354582; = p.R2288* on NM_002222.7) | Nonsense Mutation (SNP) | VAF 80/189 reads (42%) | catalogued as rs765004428, COSV56976089; called by muse, mutect2, varscan2
- ITPR3 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777019225, COSV65407660; called by muse, mutect2, varscan2
- ITPRIPL2 | c.1438C>A p.L480I | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV67347484; called by muse, mutect2, varscan2
- ITSN1 | c.4676+2T>C p.X1559_splice | Splice Site (SNP) | VAF 16/31 reads (52%) | catalogued as COSV101181378; called by muse, mutect2
- JAK1 | c.2345C>T p.T782M | Missense Mutation (SNP) | VAF 55/168 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747502464, COSV61088051; called by muse, mutect2, varscan2
- JAKMIP1 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.299); catalogued as COSV99288898; called by muse, mutect2, varscan2
- JAM3 | c.745dup p.V249Gfs*28 | Frame Shift Ins (INS) | VAF 40/160 reads (25%) | catalogued as rs763250381; called by mutect2, varscan2
- JPH4 | c.1582G>A p.G528S | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs370087602; called by muse, mutect2, varscan2
- KANSL1 | c.2788C>T p.R930W (on ENST00000574590 / NM_001193465.2; = p.R931W on NM_015443.4) | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377108187; ClinVar: likely benign; called by muse, mutect2, varscan2
- KAT6B | c.6130G>A p.G2044S | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.003); catalogued as rs374969061, COSV99768122; called by muse, mutect2, varscan2
- KATNBL1 | c.169C>T p.Q57* | Nonsense Mutation (SNP) | VAF 51/164 reads (31%) | catalogued as COSV56622657; called by muse, mutect2, varscan2
- KATNIP | c.3259C>T p.R1087* | Nonsense Mutation (SNP) | VAF 29/86 reads (34%) | catalogued as rs771883563, COSV55177228; called by muse, mutect2, varscan2
- KCNA2 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60369560; called by muse, mutect2, varscan2
- KCNB1 | c.2461A>T p.T821S | Missense Mutation (SNP) | VAF 96/241 reads (40%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.003); catalogued as COSV65567131; called by muse, mutect2, varscan2
- KCND2 | c.490A>G p.T164A | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV58575182; called by muse, mutect2
- KCNG4 | c.1520T>G p.L507R | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV57583310; called by muse, mutect2, varscan2
- KCNH3 | c.484G>T p.G162C | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV57790194; called by muse, mutect2, varscan2
- KCNH3 | c.2123del p.G708Efs*11 | Frame Shift Del (DEL) | VAF 23/62 reads (37%) | catalogued as rs1229306184; called by mutect2, pindel, varscan2
- KCNJ8 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.173); catalogued as COSV53717835; called by muse, varscan2
- KCNK10 | c.1054C>T p.R352W | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs764537069, COSV56642228, COSV56651207; called by muse, mutect2, varscan2
- KCNQ1 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.781); catalogued as rs765665086, CM136618, COSV50103907; called by muse, mutect2, varscan2
- KCNS2 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54637980; called by muse, mutect2, varscan2
- KCNU1 | c.3050T>C p.V1017A | Missense Mutation (SNP) | VAF 62/186 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV101299449, COSV67754643; called by muse, mutect2
- KCTD19 | c.2301del p.V768Wfs*38 | Frame Shift Del (DEL) | VAF 52/172 reads (30%) | catalogued as rs759860142; called by mutect2, pindel, varscan2
- KDELR1 | c.28C>A p.L10I | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV54377977; called by muse, mutect2, varscan2
- KDM2B | c.2722G>A p.D908N | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as rs895569064, COSV65639369; called by muse, mutect2, varscan2
- KDM2B | c.271+2T>C p.X91_splice | Splice Site (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100997263; called by muse, mutect2, varscan2
- KDM3B | c.853C>T p.R285W | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1422937724, COSV58689665; called by muse, mutect2, varscan2
- KDM4B | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as rs1001771201, COSV50214318; called by muse, mutect2, varscan2
- KHNYN | c.338C>A p.P113H | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV52159673; called by muse, mutect2, varscan2
- KIAA1549L | c.3351G>T p.M1117I (on ENST00000321505; = p.M1414I on NM_012194.3) | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.247); catalogued as COSV55771677; called by muse, mutect2, varscan2
- KIF13B | c.4493C>T p.P1498L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs374209248, COSV68094132; called by muse, mutect2, varscan2
- KIF18B | c.1532T>C p.V511A (on ENST00000593135 / NM_001265577.2; = p.V523A on NM_001264573.2) | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as COSV100191870; called by muse, mutect2
- KIF1C | c.172T>C p.S58P | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57903891; called by muse, mutect2, varscan2
- KIF1C | c.2479G>T p.G827W | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV57902855; called by muse, mutect2, varscan2
- KIF20A | c.2667G>C p.K889N | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV67509629; called by muse, mutect2, varscan2
- KIF4B | c.2507A>G p.D836G | Missense Mutation (SNP) | VAF 91/265 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV70528673; called by muse, mutect2, varscan2
- KIFC2 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.027); catalogued as rs756190794, COSV56760600; called by muse, mutect2, varscan2
- KIFC3 | c.1556G>A p.G519D | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101109107; called by muse, varscan2
- KIR2DL3 | c.1007T>G p.L336R | Missense Mutation (SNP) | VAF 92/285 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60896756; called by muse, mutect2
- KIRREL2 | c.1953del p.C652Afs*79 | Frame Shift Del (DEL) | VAF 16/66 reads (24%) | catalogued as rs761116739, COSV52880030; called by mutect2, pindel, varscan2
- KIZ | c.1283dup p.N428Kfs*11 | Frame Shift Ins (INS) | VAF 44/133 reads (33%) | catalogued as rs755731853; called by mutect2, varscan2
- KLHL11 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.02); catalogued as rs782656916, COSV59861738; called by muse, mutect2
- KLHL13 | c.1499C>A p.T500N | Missense Mutation (SNP) | VAF 64/207 reads (31%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.698); catalogued as COSV53246383; called by muse, mutect2, varscan2
- KLHL25 | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.065); catalogued as rs542141942, COSV61994719; called by muse, mutect2, varscan2
- KLHL34 | c.861del p.R288Afs*7 | Frame Shift Del (DEL) | VAF 38/102 reads (37%) | catalogued as rs762518653; called by mutect2, pindel
- KLHL5 | c.1292A>G p.D431G | Missense Mutation (SNP) | VAF 105/289 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV54673107; called by muse, mutect2, varscan2
- KLHL5 | c.2145dup p.Y716Vfs*2 | Frame Shift Ins (INS) | VAF 85/291 reads (29%) | catalogued as rs1213171273; called by mutect2, pindel, varscan2
- KLKB1 | c.418del p.R140Gfs*29 | Frame Shift Del (DEL) | VAF 65/203 reads (32%) | catalogued as rs755680952; called by mutect2, pindel, varscan2
- KMT2D | c.4840C>T p.R1614W | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375118713; called by muse, mutect2, varscan2
- KMT5C | c.106G>A p.V36I | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.054); catalogued as rs774927761, COSV55318841, COSV55320455; called by muse, mutect2, varscan2
- KNOP1 | c.467dup p.A158Gfs*16 | Frame Shift Ins (INS) | VAF 27/99 reads (27%) | catalogued as COSV54926489; called by mutect2, varscan2
- KPTN | c.299C>T p.T100M | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54549508; called by muse, mutect2, varscan2
- KRI1 | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1420809267, COSV57264183; called by muse, varscan2
- KRT2 | c.1225dup p.E409Gfs*10 | Frame Shift Ins (INS) | VAF 58/203 reads (29%) | catalogued as rs1260366085; called by mutect2, pindel, varscan2
- KRT26 | c.961A>G p.M321V | Missense Mutation (SNP) | VAF 218/683 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1433891764, COSV59413627; called by muse, mutect2
- KRT71 | c.1387A>G p.S463G | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs937658685, COSV99922004; called by muse, mutect2, varscan2
- KRT72 | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as COSV99537099; called by muse, mutect2, varscan2
- KRT75 | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | catalogued as rs374682761, COSV99359265; called by muse, mutect2, varscan2
- KRTAP10-10 | c.107C>A p.P36H | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as rs782137655, COSV59957203; called by muse, mutect2
- L3MBTL1 | c.1832G>T p.R611I (on ENST00000418998 / NM_001377303.1; = p.R521I on NM_015478.7) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.857); catalogued as COSV64228211; called by muse, mutect2, varscan2
- LAMA1 | c.7184A>C p.N2395T | Missense Mutation (SNP) | VAF 59/184 reads (32%) | SIFT tolerated (1); PolyPhen probably damaging (0.913); catalogued as COSV101055389; called by muse, varscan2
- LAMA1 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 57/151 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.019); catalogued as rs367866675; called by muse, mutect2, varscan2
- LAMA3 | c.3185A>G p.N1062S | Missense Mutation (SNP) | VAF 112/321 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.12); catalogued as rs369555108; called by muse, varscan2
- LAMA5 | c.1769G>A p.S590N | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.979); catalogued as COSV53357033; called by muse, mutect2, varscan2
- LARP6 | c.98A>G p.D33G | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV100150742; called by muse, mutect2, varscan2
- LARS1 | c.774T>C p.G258= (on ENST00000394434 / NM_020117.11; = p.G231= on NM_016460.3) | Splice Region (SNP) | VAF 114/354 reads (32%) | catalogued as COSV50973792; called by muse, mutect2
- LDLR | c.2547G>A p.S849= | Splice Region (SNP) | VAF 15/34 reads (44%) | catalogued as rs1249903899, COSV52942534; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LGR4 | c.2782C>T p.R928* | Nonsense Mutation (SNP) | VAF 39/90 reads (43%) | catalogued as rs1461413137, COSV58725333; called by muse, mutect2, varscan2
- LGR5 | c.2375A>G p.N792S | Missense Mutation (SNP) | VAF 130/330 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.028); catalogued as rs1398317494, COSV57003968; called by muse, varscan2
- LHCGR | c.1764dup p.A589Cfs*17 | Frame Shift Ins (INS) | VAF 52/182 reads (29%) | catalogued as rs1293879367; called by mutect2, varscan2
- LHX2 | c.173G>A p.G58D | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.111); catalogued as COSV65318062; called by muse, mutect2, varscan2
- LIG1 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 165/387 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV54390579; called by muse, mutect2, varscan2
- LIG3 | c.469dup p.I157Nfs*16 | Frame Shift Ins (INS) | VAF 31/100 reads (31%) | catalogued as rs745989900; called by mutect2, varscan2
- LIPT1 | c.813G>A p.W271* | Nonsense Mutation (SNP) | VAF 67/188 reads (36%) | catalogued as COSV60739512; called by muse, mutect2, varscan2
- LLGL2 | c.2510C>T p.A837V | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1282229640, COSV99389149; called by muse, mutect2, varscan2
- LMAN2L | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as rs1289758319, COSV53841224; called by muse, mutect2, varscan2
- LMF1 | c.164T>C p.V55A | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.265); catalogued as COSV99234748; called by muse, mutect2
- LMNTD1 | c.770A>G p.Q257R | Missense Mutation (SNP) | VAF 63/198 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as COSV51445809; called by muse, mutect2, varscan2
- LMO7 | c.1882C>T p.R628C (on ENST00000357063; = p.R358C on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs190179934, COSV58530576; called by muse, mutect2, varscan2
- LMOD1 | c.1336A>G p.T446A | Missense Mutation (SNP) | VAF 81/222 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV100939100; called by muse, mutect2, varscan2
- LPO | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs771008787, COSV51857909; called by muse, mutect2, varscan2
- LRFN3 | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55817313; called by muse, mutect2, varscan2
- LRGUK | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 64/158 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as rs200351099; called by muse, mutect2, varscan2
- LRIG2 | c.404T>C p.I135T | Missense Mutation (SNP) | VAF 140/495 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as COSV63161560; called by muse, mutect2, varscan2
- LRIT1 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.574); catalogued as COSV64512235; called by muse, mutect2, varscan2
- LRP12 | c.668T>C p.L223S | Missense Mutation (SNP) | VAF 83/233 reads (36%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.998); catalogued as COSV52627452; called by muse, mutect2, varscan2
- LRP1B | c.11895T>C p.C3965= | Splice Region (SNP) | VAF 58/154 reads (38%) | catalogued as COSV101253843; called by muse, mutect2, varscan2
- LRP2 | c.10652G>A p.R3551H | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs545303364, COSV55548085; called by muse, mutect2, varscan2
- LRP3 | c.2296G>A p.A766T | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV53503249, COSV53505126; called by muse, mutect2, varscan2
- LRRC17 | c.989A>G p.N330S | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV50864398; called by muse, mutect2, varscan2
- LRRC25 | c.898T>C p.Y300H | Missense Mutation (SNP) | VAF 53/170 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV53250739; called by muse, mutect2, varscan2
- LRRC28 | c.797A>C p.E266A | Missense Mutation (SNP) | VAF 144/402 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV57337000; called by muse, mutect2
- LRRC57 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1002033646, COSV52999429; called by muse, mutect2, varscan2
- LRRC8D | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs773687858, COSV61578411; called by muse, mutect2, varscan2
- LRRFIP1 | c.842C>T p.T281I (on ENST00000392000 / NM_001137552.2; = p.T257I on NM_004735.4) | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55250396; called by muse, mutect2
- LTBP3 | c.926C>T p.T309I | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100099156; called by muse, mutect2
- LTBP4 | c.3977del p.P1326Hfs*103 (on ENST00000308370 / NM_001042544.1; = p.P1289Hfs*103 on NM_003573.2) | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | catalogued as COSV52588056; called by mutect2, pindel, varscan2
- LUZP1 | c.2782C>T p.R928* | Nonsense Mutation (SNP) | VAF 66/191 reads (35%) | catalogued as COSV56500113; called by muse, mutect2, varscan2
- LUZP4 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 240/641 reads (37%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs936115318, COSV64218417; called by muse, varscan2
- LY6G6F-LY6G6D | c.899T>C p.L300P | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated, low confidence (0.34); PolyPhen possibly damaging (0.502); catalogued as COSV101010808; called by muse, mutect2
- LY9 | c.1618A>G p.N540D | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.169); catalogued as COSV99626313; called by muse, mutect2, varscan2
- LYPD4 | c.212-1G>A p.X71_splice | Splice Site (SNP) | VAF 13/28 reads (46%) | catalogued as COSV58027644; called by muse, mutect2
- LZTR1 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.195); catalogued as rs570948606, COSV53146508, COSV99302403; called by muse, mutect2, varscan2
- MACF1 | c.17293A>G p.S5765G (on ENST00000372915; = p.S3807G on NM_012090.5) | Missense Mutation (SNP) | VAF 56/158 reads (35%) | catalogued as COSV57115097; called by muse, mutect2, varscan2
- MAD1L1 | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs771673407, COSV56231308; called by muse, mutect2, varscan2
- MAF | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.236); catalogued as COSV58153592; called by muse, mutect2, varscan2
- MAGEL2 | c.3325A>G p.K1109E | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.275); catalogued as COSV58566524; called by muse, mutect2
- MAGIX | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 78/221 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as COSV66255857; called by muse, mutect2, varscan2
- MAN1C1 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs867433498, COSV56043914; called by muse, mutect2, varscan2
- MAN1C1 | c.1366G>A p.G456R | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769693980, COSV56043923; called by muse, varscan2
- MAP1A | c.2020G>A p.A674T | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs376517161; called by muse, mutect2, varscan2
- MAP1A | c.4154C>T p.T1385I | Missense Mutation (SNP) | VAF 71/200 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs1190233308, COSV55807625; called by muse, mutect2, varscan2
- MAP1S | c.2560del p.R854Gfs*156 | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | catalogued as COSV60722182; called by mutect2, pindel, varscan2
- MAP2K5 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 62/176 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs532904399, COSV51612620; called by muse, mutect2, varscan2
- MAP2K7 | c.1225G>A p.V409I | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.005); catalogued as rs775112625, COSV67607944; called by muse, mutect2, varscan2
- MAP3K1 | c.3931G>T p.G1311* | Nonsense Mutation (SNP) | VAF 122/316 reads (39%) | catalogued as COSV68122853; called by muse, mutect2, varscan2
- MAP3K21 | c.2873A>T p.Q958L | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV64041417; called by muse, varscan2
- MAP3K21 | c.2908C>T p.Q970* | Nonsense Mutation (SNP) | VAF 29/90 reads (32%) | catalogued as rs758435545, COSV64041428; called by muse, varscan2
- MAP4 | c.1948G>A p.E650K | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.114); catalogued as rs1263717043, COSV99274837; called by muse, mutect2
- MAP4K2 | c.833C>A p.P278H | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV53642034; called by muse, mutect2, varscan2
- MAP4K5 | c.2368A>G p.M790V | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.986); catalogued as COSV50153418; called by muse, mutect2, varscan2
- MAPK8 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 12/233 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.861); catalogued as COSV100827386; called by muse, mutect2
- MARCHF4 | c.517G>T p.G173W | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56104209, COSV56109582; called by muse, mutect2
- MARCKS | c.980dup p.A328Sfs*14 | Frame Shift Ins (INS) | VAF 36/72 reads (50%) | catalogued as rs770972906; called by mutect2, varscan2
- MARK1 | c.1537C>T p.R513* | Nonsense Mutation (SNP) | VAF 72/279 reads (26%) | catalogued as COSV65066674; called by muse, mutect2, varscan2
- MARS2 | c.632A>G p.Y211C | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56571032; called by muse, mutect2, varscan2
- MASTL | c.1994C>A p.S665Y | Missense Mutation (SNP) | VAF 67/186 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs112048111, COSV60910221; called by muse, mutect2, varscan2
- MATN3 | c.509T>C p.M170T | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV68099637; called by muse, mutect2
- MBD5 | c.3377T>C p.F1126S | Missense Mutation (SNP) | VAF 73/185 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV68696325; called by muse, mutect2, varscan2
- MCF2 | c.2012C>T p.S671L | Missense Mutation (SNP) | VAF 26/618 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1328580247, COSV100644548; called by muse, mutect2
- MCM7 | c.1576G>A p.D526N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.387); catalogued as rs765971073, COSV57995346; called by muse, mutect2, varscan2
- MCTS1 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 160/494 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV64892369; called by muse, varscan2
- MDC1 | c.4030C>A p.P1344T | Missense Mutation (SNP) | VAF 120/341 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV64524059; called by muse, mutect2, varscan2
- MDN1 | c.12746A>G p.Q4249R | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.494); catalogued as COSV65519951; called by muse, mutect2
- MDN1 | c.3765C>A p.S1255= | Splice Region (SNP) | VAF 26/82 reads (32%) | catalogued as COSV101020882; called by muse, mutect2, varscan2
- MED12 | c.99G>T p.E33D | Missense Mutation (SNP) | VAF 58/191 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV61336158; called by muse, mutect2, varscan2
- MED12 | c.5057C>T p.S1686L | Missense Mutation (SNP) | VAF 20/310 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV61333652; called by muse, mutect2
- MED15 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.007); catalogued as COSV53028277; called by muse, mutect2, varscan2
- MEGF8 | c.5007del p.T1670Qfs*60 (on ENST00000251268 / NM_001271938.2; = p.T1603Qfs*60 on NM_001410.3) | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | catalogued as COSV99233906; called by mutect2, pindel, varscan2
- MEI1 | c.575A>C p.E192A | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100299699; called by muse, mutect2
- MEPE | c.1526A>G p.D509G | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); catalogued as COSV63072377; called by muse, mutect2, varscan2
- METTL22 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1385109586, COSV50837558; called by muse, mutect2, varscan2
- MFSD12 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as COSV100281290; called by muse, mutect2, varscan2
- MFSD2A | c.1196C>T p.A399V (on ENST00000372809 / NM_001136493.3; = p.A386V on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/177 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs139973362; called by muse, mutect2, varscan2
- MGAT4C | c.1174dup p.I392Nfs*2 | Frame Shift Ins (INS) | VAF 46/84 reads (55%) | catalogued as rs746398787; called by mutect2, varscan2
- MICALL1 | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 39/112 reads (35%) | catalogued as COSV53239926; called by muse, mutect2, varscan2
- MICOS13 | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs546864089, COSV100028484; called by muse, varscan2
- MIER2 | c.1513T>C p.S505P | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53395011; called by muse, mutect2, varscan2
- MIER3 | c.1391A>T p.E464V (on ENST00000381199 / NM_001297599.2; = p.E463V on NM_152622.4) | Missense Mutation (SNP) | VAF 60/203 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.796); catalogued as COSV67082714; called by muse, mutect2, varscan2
- MINDY1 | c.1096C>A p.L366M | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV56498251; called by muse, mutect2, varscan2
- MLLT1 | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as rs767911025, COSV53129959, COSV53130123; called by muse, mutect2
- MLST8 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 28/107 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.599); catalogued as COSV57027407; called by muse, mutect2, varscan2
- MMACHC | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV53113422; called by muse, mutect2, varscan2
- MMP9 | c.1337G>A p.R446H | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs968520149, COSV63433933; called by muse, mutect2, varscan2
- MNDA | c.907G>T p.A303S | Missense Mutation (SNP) | VAF 111/318 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV63740420, COSV63741739; called by muse, mutect2, varscan2
- MOGAT3 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs763725968, COSV56173670; called by muse, mutect2, varscan2
- MON1B | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1271811473, COSV50246034; called by muse, mutect2, varscan2
- MPL | c.500A>G p.Y167C | Missense Mutation (SNP) | VAF 53/204 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as COSV65244537; called by muse, mutect2, varscan2
- MPO | c.2018G>T p.R673L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51856581, COSV51857911; called by muse, mutect2, varscan2
- MRI1 | c.988del p.H330Tfs*24 (on ENST00000040663 / NM_001031727.4; = p.H283Tfs*24 on NM_032285.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 60/190 reads (32%) | catalogued as rs751646149; called by mutect2, pindel, varscan2
- MROH2B | c.3176T>C p.V1059A | Missense Mutation (SNP) | VAF 95/213 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV101270571; called by muse, mutect2, varscan2
- MRPL19 | c.475+2T>C p.X159_splice | Splice Site (SNP) | VAF 110/391 reads (28%) | catalogued as COSV62566848; called by muse, mutect2, varscan2
- MRTFA | c.1736T>C p.M579T | Missense Mutation (SNP) | VAF 64/156 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.337); catalogued as COSV62932483; called by muse, mutect2
- MSL3 | c.1319del p.P440Qfs*22 (on ENST00000312196 / NM_078629.4; = p.P274Qfs*22 on NM_006800.4) | Frame Shift Del (DEL) | VAF 45/176 reads (26%) | catalogued as rs768515139; called by mutect2, pindel, varscan2
- MTF2 | c.1188del p.G397Efs*6 | Frame Shift Del (DEL) | VAF 13/32 reads (41%) | catalogued as rs759847587; called by mutect2, varscan2
- MTMR8 | c.440C>T p.T147I | Missense Mutation (SNP) | VAF 125/414 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV66393106; called by muse, mutect2, varscan2
- MTTP | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as rs201464944; called by muse, mutect2, varscan2
- MUC16 | c.35567C>T p.T11856I | Missense Mutation (SNP) | VAF 82/254 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV67456939; called by muse, varscan2
- MUC16 | c.35539del p.T11847Qfs*15 | Frame Shift Del (DEL) | VAF 75/254 reads (30%) | catalogued as rs761846387; called by pindel, varscan2
- MUC17 | c.7511T>C p.V2504A | Missense Mutation (SNP) | VAF 61/166 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100072032; called by muse, varscan2
- MUC17 | c.10088C>A p.T3363N | Missense Mutation (SNP) | VAF 60/165 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV60284815; called by muse, mutect2, varscan2
- MUC4 | c.12739A>G p.T4247A | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.028); catalogued as COSV57773033; called by muse, varscan2
1,383 further variants in this file (898 protein-altering or splice-affecting, 440 silent, 45 other) are not listed here.
